Somatic mutation profile of tumor specimen TCGA-AQ-A1H2-01A (aliquot TCGA-AQ-A1H2-01A-11D-A13L-09) from TCGA case TCGA-AQ-A1H2, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 84.8 years (30,958 days).
Specimen TCGA-AQ-A1H2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8e93af4-daa8-434a-bc66-b898ca2a4ae8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AQ-A1H2-10A (Blood Derived Normal), aliquot TCGA-AQ-A1H2-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8913982-1211-4bbd-9738-363526e8c79b

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 3, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CLSPN | c.3415C>T p.R1139* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as rs1344308365, COSV52051490; called by muse, mutect2, varscan2
- ENPP2 | c.1294C>T p.R432C (on ENST00000075322 / NM_001040092.3; = p.R484C on NM_006209.5) | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1201156778, COSV50015906; called by muse, mutect2, varscan2
- FAT1 | c.5284G>A p.A1762T | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs371394820; called by muse, mutect2, varscan2
- GRIK1 | c.2734T>C p.S912P (on ENST00000327783 / NM_001330994.2; = p.S868P on NM_175611.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV59867639; called by muse, mutect2, varscan2
- KIF9 | c.691T>G p.L231V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.222); catalogued as COSV55519792; called by muse, mutect2, varscan2
- KMT2C | c.620del p.S207Ffs*3 | Frame Shift Del (DEL) | VAF 30/54 reads (56%) | catalogued as COSV51443842; called by mutect2, pindel, varscan2
- LPA | c.5566G>C p.V1856L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV60302496; called by muse, mutect2, varscan2
- LPCAT4 | c.855T>A p.Y285* | Nonsense Mutation (SNP) | VAF 22/41 reads (54%) | catalogued as COSV59217039; called by muse, mutect2, varscan2
- MDGA1 | c.1183G>C p.A395P | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV51796299; called by muse, mutect2, varscan2
- MNT | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51512406; called by muse, mutect2, varscan2
- MYH15 | c.4228C>T p.Q1410* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as rs1310644215, COSV56310932; called by muse, mutect2, varscan2
- PCDHGA2 | c.286T>A p.C96S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1327200559, COSV53955537; called by muse, mutect2, varscan2
- PHOX2B | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV56929639; called by muse, mutect2, varscan2
- POLR2A | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.657); catalogued as rs139873836; called by muse, mutect2, varscan2
- PRPF6 | c.1913A>G p.N638S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs756373021, COSV53871231; called by muse, mutect2, varscan2
- ROBO1 | c.440G>A p.C147Y | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71394652; called by muse, mutect2, varscan2
- SLC49A4 | c.1056_1058del p.L353del | In Frame Del (DEL) | VAF 44/108 reads (41%) | catalogued as rs769857659; called by pindel, varscan2
- SPEN | c.8537_8538insCT p.E2846Dfs*44 | Frame Shift Ins (INS) | VAF 21/35 reads (60%) | catalogued as COSV65362617; called by mutect2, pindel, varscan2
- SPRY3 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57142219; called by muse, mutect2, varscan2
- TRAPPC1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1035892248, COSV58050299; called by muse, mutect2, varscan2
- YTHDC1 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100704878, COSV60012207; called by muse, mutect2, varscan2
- ATP6V0B | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRF3 | c.2817G>A p.V939= (on ENST00000311519 / NM_001145168.1; = p.V740= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV61050547; called by muse, mutect2, varscan2
- COL9A2 | c.357A>T p.G119= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV65607597; called by muse, mutect2, varscan2
- CPLX2 | c.378G>A p.G126= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV64000677; called by muse, mutect2, varscan2
- DCLRE1A | c.2193A>G p.T731= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV63748836; called by muse, mutect2, varscan2
- SLITRK2 | c.72T>A p.T24= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs1556943713, COSV100158263; called by muse, mutect2, varscan2
- UBASH3A | c.150G>A p.A50= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs140628973; called by muse, mutect2, varscan2
- YY2 | c.273C>T p.C91= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs1196997673, COSV63411615; called by muse, mutect2, varscan2
- ADAM8 | c.*56G>A | 3'UTR (SNP) | VAF 22/53 reads (42%) | catalogued as rs554340450, COSV101291750; called by muse, mutect2, varscan2
- WASF4P | n.515T>C | RNA (SNP) | VAF 120/253 reads (47%) | called by muse, mutect2, varscan2
